Somatic mutation profile of tumor specimen TCGA-DD-AAVW-01A (aliquot TCGA-DD-AAVW-01A-11D-A40R-10) from TCGA case TCGA-DD-AAVW, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 35.6 years (12,986 days).
Specimen TCGA-DD-AAVW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e29495df-83ed-4401-b4b6-ad7506d1889f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAVW-10A (Blood Derived Normal), aliquot TCGA-DD-AAVW-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44431fa0-0360-4d89-9279-dc07bcd5659a

The open-access MAF lists 34 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 6, Translation Start Site 1, Intron 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APP | c.1052A>G p.K351R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.678); catalogued as rs1368804197, COSV100695279; called by muse, mutect2, varscan2
- CACNA1C | c.6575G>T p.G2192V (on ENST00000399634 / NM_001167625.1; = p.G2121V on NM_000719.7) | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.01); catalogued as COSV100215532; called by muse, mutect2, varscan2
- CBY2 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs769761456, COSV100137442; called by muse, mutect2, varscan2
- CUX2 | c.2951C>T p.S984L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs756425143, COSV99918662; called by muse, varscan2
- GPR158 | c.3356A>C p.E1119A | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV100892897; called by muse, mutect2, varscan2
- GUCY1A1 | c.1862C>A p.T621K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs183373438, COSV99637162; called by muse, mutect2, varscan2
- ITGA10 | c.2476G>C p.V826L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.189); catalogued as COSV100994723; called by muse, mutect2
- LSS | c.310_311insA p.L104Hfs*35 | Frame Shift Ins (INS) | VAF 9/44 reads (20%) | catalogued as COSV100710801; called by mutect2, pindel, varscan2
- MAN2B2 | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1205209076, COSV53451661; called by muse, mutect2, varscan2
- MKI67 | c.617T>C p.I206T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as COSV100896179; called by muse, mutect2, varscan2
- P3H3 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782171760, COSV51831713; called by muse, mutect2, varscan2
- PCDHGA6 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV53997263; called by muse, mutect2, varscan2
- PCDHGB2 | c.1376T>C p.V459A | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.976); catalogued as COSV99531097; called by muse, mutect2, varscan2
- PDCD11 | c.5224G>T p.A1742S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV99588257; called by muse, mutect2, varscan2
- PDGFRA | c.2941C>T p.R981C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs775205485, COSV57268573; ClinVar: uncertain significance; called by mutect2, varscan2
- PRRT3 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs1276909885, COSV99926336; called by muse, mutect2, varscan2
- PYGM | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99376738; called by muse, mutect2, varscan2
- RSBN1L | c.262T>G p.F88V | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.04); catalogued as COSV100615896; called by muse, mutect2, varscan2
- RUNX1T1 | c.890C>T p.P297L (on ENST00000265814 / NM_001198628.1; = p.P270L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV99749604; called by muse, mutect2, varscan2
- RYR1 | c.5453C>T p.A1818V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs1274823763, COSV62092082, COSV62113411; called by muse, mutect2, varscan2
- SLAMF9 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as rs147539315, COSV100928123; called by muse, mutect2, varscan2
- SLC9C1 | c.1591T>C p.Y531H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99997342; called by mutect2, varscan2
- TRIM10 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs137941157, COSV100939618; called by muse, mutect2, varscan2
- TRIM28 | c.674A>T p.D225V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99448700; called by muse, mutect2, varscan2
- TSPYL5 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99079697; called by muse, mutect2
- UNC45B | c.2682C>G p.I894M | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52099245, COSV99268230; called by muse, mutect2, varscan2
- HOOK2 | c.991del p.V331Cfs*51 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- ATL2 | c.66G>A p.R22= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as COSV100184422; called by muse, mutect2
- C2orf66 | c.177A>T p.T59= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100692792; called by muse, mutect2, varscan2
- C3 | c.996G>A p.L332= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV99836091; called by muse, mutect2, varscan2
- COPG1 | c.1632A>G p.A544= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs967042433, COSV100135369; called by muse, mutect2, varscan2
- OR2J3 | c.600G>T p.L200= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV101013553; called by muse, mutect2, varscan2
- RPTOR | c.972G>A p.A324= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs375226529; called by muse, mutect2, varscan2
- NACA | c.70+4710G>A | Intron (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100771081; called by muse, mutect2, varscan2
